Gene-level copy-number profile of tumor specimen C3L-01283-01 from CPTAC case C3L-01283, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 37.0 years (13,526 days).
Specimen C3L-01283-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 98e69e82-ff9d-43e9-b96b-af17fff32078.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3L-01283-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/2deabf69-7d71-498f-b3c4-d94c7b4f64cf

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 623; copy number 1: 5,447; copy number 2: 52,714; copy number 3: 116; copy number 4: 13.

Homozygous deletions (total copy number 0; autosomes only): 112 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:79,661,394–79,826,594, 1 gene (within-gene range 0–2): NUTM2B-AS1.
- chr10:79,703,227–79,827,602, 2 genes (within-gene range 0–2): NUTM2B, AL135925.1.
- chr14:21,941,128–22,552,156, 109 genes (within-gene range 0–2) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 3,104. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
